Somatic mutation profile of tumor specimen TARGET-10-PASNTZ-09A (aliquot TARGET-10-PASNTZ-09A-01D) from TARGET case TARGET-10-PASNTZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.2 years (2,627 days).
Specimen TARGET-10-PASNTZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a66b572-d87f-448d-aac0-e447ec3a28bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASNTZ-10A (Blood Derived Normal), aliquot TARGET-10-PASNTZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7453371d-0769-44e1-b0dd-7352f628720a

The open-access MAF lists 33 somatic variants for this specimen: 25 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 6, Frame Shift Ins 2, In Frame Ins 2, 5'UTR 1, Frame Shift Del 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RUNX1 | c.530G>A p.R177Q (on ENST00000344691 / NM_001001890.3; = p.R204Q on NM_001754.5) | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1569061762, CM093278, COSV55866469, COSV55875660, COSV55875973; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AOC3 | c.1998T>A p.N666K | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV53825253; called by muse, mutect2, varscan2
- DHX15 | c.1169C>G p.S390C | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61026143; called by muse, mutect2, varscan2
- EPHA8 | c.490C>T p.L164F | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51265049; called by muse, mutect2, varscan2
- EVA1A | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52057497; called by muse, mutect2, varscan2
- FASN | c.3733G>A p.V1245M | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.519); catalogued as rs762888619; called by muse, varscan2
- GNAS | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 55/93 reads (59%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1295350827, COSV58330745; called by muse, mutect2, varscan2
- HMCN2 | c.11383G>A p.G3795R | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as rs983360056; called by muse, mutect2, varscan2
- JAK3 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs752661478, COSV71685384, COSV71685422, COSV71685783; called by muse, mutect2, varscan2
- KCNV2 | c.941C>T p.T314M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs543611672, COSV66055515; called by muse, mutect2, varscan2
- KIF13A | c.4753G>C p.E1585Q | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.007); catalogued as COSV52446159, COSV99435856; called by muse, mutect2, varscan2
- LRRTM1 | c.762G>C p.W254C | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV54439538; called by muse, mutect2, varscan2
- NOTCH1 | c.7541_7542del p.P2514Rfs*4 | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | catalogued as rs763016003, COSV53024776; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NOTCH1 | c.4775_4776insTGC p.F1592_L1593insA | In Frame Ins (INS) | VAF 12/30 reads (40%) | catalogued as COSV53024877, COSV53028189, COSV53038773, COSV53042822, COSV53047824, COSV53049150, COSV53050117, COSV53053941, COSV53058597, COSV53059642, COSV53059832, COSV53063931, COSV53065478, COSV53068542, COSV53073834, COSV5…; called by mutect2, varscan2
- PHF6 | c.834+1G>C p.X278_splice (on ENST00000332070 / NM_032458.3; = p.V280L on NM_032335.3) | Splice Site (SNP) | VAF 29/30 reads (97%) | catalogued as COSV59699694, COSV59699754; called by muse, mutect2, varscan2
- PINK1 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.966); catalogued as rs748041977, COSV58630774, COSV58632458; called by muse, mutect2, varscan2
- PTDSS1 | c.806C>A p.P269H | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61264048; called by muse, mutect2, varscan2
- TMTC2 | c.2428C>T p.P810S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1357701567; called by muse, mutect2
- UBE2I | c.370_371insTTACTCGCCACCGTTTTTATAATCC p.N124Ifs*70 | Frame Shift Ins (INS) | VAF 31/108 reads (29%) | catalogued as COSV57646568; called by mutect2, pindel, varscan2
- USP29 | c.2615C>T p.A872V | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.961); catalogued as rs200727021; called by muse, mutect2, varscan2
- ABCA1 | c.1827_1829dup p.G610dup | In Frame Ins (INS) | VAF 13/31 reads (42%) | called by mutect2, pindel, varscan2
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 7/28 reads (25%) | called by pindel, varscan2
- CELSR1 | c.2056G>C p.V686L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.014); called by muse, mutect2
- DHX15 | c.1262C>A p.T421N | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HS6ST3 | c.286G>A p.G96R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.652); called by muse, varscan2
- CTNNA2 | c.2019G>A p.A673= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs765021278, COSV58166048, COSV58178978; called by mutect2, varscan2
- HS3ST3B1 | c.663C>G p.T221= | Silent (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- KSR2 | c.1923G>A p.S641= | Silent (SNP) | VAF 30/66 reads (45%) | catalogued as rs377379360; called by muse, mutect2, varscan2
- NCAM2 | c.2130T>C p.A710= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as rs1294157164; called by muse, mutect2, varscan2
- POU6F2 | c.81G>A p.A27= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as rs376754165, COSV101302892; called by muse, mutect2, varscan2
- STARD13 | c.1077C>T p.R359= (on ENST00000336934 / NM_001243476.3; = p.R241= on NM_052851.3) | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs200783157, COSV55238835; called by muse, mutect2, varscan2
- AC092718.9 | chr16:81149796 G>A | 5'Flank (SNP) | VAF 15/51 reads (29%) | catalogued as rs764041345; called by muse, mutect2, varscan2
- TSTD1 | c.-34C>G | 5'UTR (SNP) | VAF 14/35 reads (40%) | catalogued as rs1351408058; called by muse, mutect2, varscan2
